Somatic mutation profile of tumor specimen TARGET-10-PATLPN-03A (aliquot TARGET-10-PATLPN-03A-01D) from TARGET case TARGET-10-PATLPN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (945 days).
Specimen TARGET-10-PATLPN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 107912b6-aebd-47ce-bdd8-ddca9e167176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLPN-10A (Blood Derived Normal), aliquot TARGET-10-PATLPN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/745ac9d2-bcc3-4a92-95fb-f5367bf4c8fe

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN1B | c.475+1G>T p.X159_splice | Splice Site (SNP) | VAF 53/138 reads (38%) | hotspot (GDC flag); catalogued as rs1174921391, COSV57429560, COSV57429633; called by mutect2, varscan2
